Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A8NG, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A8NG-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3

Adenocarcinoma NOS 8140/3

Site ^{CCE} Esophagus distal third
C15.5

^{path} Gastroesophageal junction
C16.0

Q10 1/17/14

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

year-old male with long history of heartburn/food indigestion. Developed dysphagia and weight loss. On , barium swallow showed concentric filling defect in distal esophagus. On chest CT showed a 1 cm elliptical nodule in the lateral segment RML; circumferential thickening of

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 3
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

the distal esophagus. Clinical Diagnosis: Cancer, primary esophagus.
Operative Procedure: THE.

PROCEDURE: SPGD

VERIFIED BY:

1. "Esophagus." A 13 x 5 cm specimen consisting of 6 cm of distal esophagus and 6.5 cm of the proximal stomach. 2 to 2.5 cm caudal to the GE junction, there is an irregular tongue of pink, velvety mucosa, with 1 x 1 cm and 2.5 x 1.5 cm somewhat excavated areas, suspicious for ulceration. Along the border of pink-tan, velvety mucosa and grey-tan, normal-appearing esophageal mucosa are multiple grey-tan papillations. The esophageal wall is up to 0.9 cm thick at the GE junction. The proximal gastric rugae are markedly thickened. There is a 1.2 cm mucosal punch-out defect, 1.5 cm distal to the proximal resection edge. There is a 1.5 cm circumferential infiltrating neoplasm arising just above the GE junction, which appears to extend into the muscularis propria.
1A. Distal gastric resection margin.
1B-1E. Sequential segments of the specimen from cephalad to caudad, proximal end inked green.
1F-1H. Deeper tumor extension.
1I & 1J. Representative sections of the tumor.
1K. Punched-out lesion in the proximal area.
1L & 1M. Multiple lymph nodes identified in the periesophageal fat.
2. "Cervical margin." A 2 x 2 cm fragment of tubular esophagus, stapled at one end, with pink-grey, unremarkable mucosa. Bisected. Entirely submitted with 2A being the margin.

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma.

Adenocarcinoma arising GE junction.

Depth of invasion: Adventitia.

Number of positive lymph nodes: One.

Extranodal metastasis: Unknown.

Pattern of invasion: Infiltrative.

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 4
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

Esophageal and gastric resection margins involved: No (close).

Deep resection margin involved: No (close).

TNM classification: T3 N1 Mx

PROCEDURE:

VERIFIED BY:

1-2. Esophagus, transhiatal esophagectomy: Adenocarcinoma arising at the esophagogastric junction without associated Barrett's mucosa. Neoplasm extends through the muscularis propria to within 0.1 cm of the inked periesophageal soft tissue surgical margin. Cervical esophageal surgical resection margin negative. Adenocarcinoma extends to within 0.1 cm of distal gastric resection margin. Angiolymphatic invasion identified. Metastatic adenocarcinoma involving one of four periesophageal lymph nodes. Please see template for details.

I, the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

HIIPAA Discrepancy		

Handwritten notes: 12/12/13, bmt cell, P.D. 13

Source: NCI Genomic Data Commons file 8f424183-7651-4d88-889d-1eed1c533fb5 (TCGA-L5-A8NG.2623CC3D-029B-4A18-AC25-86AFCCDE144E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).